Gene-level copy-number profile of tumor specimen TCGA-BR-A4PD-01A from TCGA case TCGA-BR-A4PD, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 72.1 years (26,334 days).
Specimen TCGA-BR-A4PD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.d102e5ff-4fdb-45a3-ad15-ec6abb14f6bd.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BR-A4PD-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 817 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/40c22f19-16e5-4cb6-86ca-2a501563cc5a

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 35; copy number 2: 6,222; copy number 3: 22,588; copy number 4: 14,694; copy number 5: 11,380; copy number 6: 2,345; copy number 7: 769; copy number 8: 370; copy number 9: 620; copy number 10: 160; copy number 11: 332; copy number 12: 110; copy number 21: 14; copy number 33: 82; copy number 43: 50; copy number 44: 24.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BR-A4PD-01A-11D-A253-01): tumor purity 0.43, ploidy 4.26, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,732,636, 5 genes: AC104164.2, MIR548BB, PPIAP70, AC104164.1, PPIAP71.
- chr20:14,757,563–15,022,958, 5 genes: RPS10P2, MACROD2-AS1, AL138808.1, RNU6-1159P, RNU6-115P.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,531 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:35,713,877–45,624,057, 334 genes, copy number 9–10 (broad region; genes not listed).
- chr1:79,967,733–81,992,436, 25 genes, copy number 7 (within-gene range 5–7): AC099671.1, AC098657.1, AC098657.2, AC098657.3, HMGB1P18, AL606519.1, HNRNPA1P64, AL596276.1, AL596276.2, AL136234.1, LINC01781, MTND2P30, RPL7P10, AL357632.1, AC093154.1, RN7SKP247, ADGRL2, HNRNPA3P14, ARID3BP1, AL138799.1, AL138799.3, MED28P8, AC117944.1, AL138799.2, ST13P20.
- chr1:149,782,671–151,729,805, 110 genes, copy number 12 (broad region; genes not listed).
- chr2:172,137,345–172,736,206, 13 genes, copy number 7 (within-gene range 4–7): AC104088.1, AC104088.3, AC104088.2, AC078883.3, ITGA6, AC078883.2, ITGA6-AS1, AC078883.1, PDK1, Y_RNA, AC018712.1, RAPGEF4-AS1, AC018712.2.
- chr2:175,072,250–175,843,302, 9 genes, copy number 9: ATF2, AC007435.1, MIR933, AC096649.1, ATP5MC3, Y_RNA, RPS15AP14, AC093459.1, EXTL2P1.
- chr2:190,880,797–192,194,933, 22 genes, copy number 11: AC005540.1, GLS, STAT1, RAB1AP1, AC067945.1, AC067945.2, STAT4, AC067945.3, RNU6-959P, AC079777.1, HMGB1P27, AC092614.1, MYO1B, RNU6-1045P, NABP1, AC114778.1, NABP1-OT1, AC098872.1, CAVIN2, CAVIN2-AS1, DNAJB1P1, TMEFF2.
- chr7:86,216,785–107,629,170, 466 genes, copy number 8–33 (within-gene range 5–33) (broad region; genes not listed).
- chr19:47,745,546–58,605,223, 827 genes, copy number 7–11 (broad region; genes not listed).
- chr20:31,257,664–59,516,039, 724 genes, copy number 7–44 (broad region; genes not listed).
- chr20:59,624,904–59,628,295, 1 gene, copy number 9: PHACTR3-AS1.

Autosomal genes at a single copy (total copy number 1): 35. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
